Somatic mutation profile of tumor specimen C3L-02613-03 (aliquot CPT0124610007_1) from CPTAC case C3L-02613, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 52.2 years (19,066 days).
Specimen C3L-02613-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7cb36d7-532b-447b-bc31-97e0b0a282a9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02613-31 (Blood Derived Normal), aliquot CPT0124640002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a86dc1a9-4661-484a-899c-aec48a7cad32

The open-access MAF lists 167 somatic variants for this specimen: 115 protein-altering or splice-affecting, 34 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 94, Silent 34, Intron 10, Nonsense Mutation 7, Frame Shift Del 6, 5'UTR 3, RNA 3, 5'Flank 2, Splice Site 2, Splice Region 2, In Frame Del 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.798del p.F266Lfs*11 | Frame Shift Del (DEL) | VAF 36/90 reads (40%) | catalogued as rs886040739; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 357/744 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.839G>T p.R280I | Missense Mutation (SNP) | VAF 473/1043 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AKAP12 | c.4234G>A p.V1412I | Missense Mutation (SNP) | VAF 37/367 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as rs569396619; called by muse, mutect2, varscan2
- ANKRD17 | c.6492G>A p.M2164I | Missense Mutation (SNP) | VAF 233/742 reads (31%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as COSV58219878; called by muse, mutect2, varscan2
- CDH12 | c.2239G>A p.V747M | Missense Mutation (SNP) | VAF 88/1390 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.347); catalogued as rs763180534, COSV66389256; called by muse, mutect2
- CDH23 | c.7714C>A p.Q2572K | Missense Mutation (SNP) | VAF 60/833 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs867364295; called by muse, mutect2
- CELSR3 | c.2110G>A p.A704T | Missense Mutation (SNP) | VAF 200/462 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.769); catalogued as rs767164011; called by muse, mutect2, varscan2
- COBLL1 | c.593T>G p.I198R (on ENST00000392717; = p.I160R on NM_014900.5) | Missense Mutation (SNP) | VAF 97/385 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99528586; called by muse, mutect2, varscan2
- COL6A6 | c.764G>T p.S255I | Missense Mutation (SNP) | VAF 217/652 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.092); catalogued as COSV62031119; called by muse, mutect2, varscan2
- CSMD3 | c.9613A>G p.M3205V (on ENST00000297405 / NM_001363185.1; = p.M3036V on NM_052900.3) | Missense Mutation (SNP) | VAF 68/552 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as rs762522299, COSV52331748; called by muse, mutect2, varscan2
- DLGAP3 | c.371A>T p.Q124L | Missense Mutation (SNP) | VAF 316/983 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as COSV99332805; called by muse, mutect2, varscan2
- DUOX2 | c.2831G>T p.G944V | Missense Mutation (SNP) | VAF 180/664 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.147); catalogued as rs1566973702; called by muse, mutect2, varscan2
- HOXB4 | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV60178853; called by mutect2, varscan2
- IL1RAPL1 | c.911G>A p.R304K | Missense Mutation (SNP) | VAF 129/460 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.021); catalogued as COSV100150938; called by mutect2, varscan2
- INO80 | c.1991G>A p.R664H | Missense Mutation (SNP) | VAF 17/375 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62737472, COSV62739062; called by muse, mutect2
- IRX3 | c.65C>A p.A22D | Missense Mutation (SNP) | VAF 86/221 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.036); catalogued as rs1372716324, COSV61668654; called by muse, mutect2, varscan2
- LAMA1 | c.6515G>A p.R2172Q | Missense Mutation (SNP) | VAF 107/355 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs746251281; called by muse, mutect2, varscan2
- MTTP | c.618G>A p.Q206= | Splice Region (SNP) | VAF 152/484 reads (31%) | catalogued as rs1454222756; called by muse, mutect2, varscan2
- NAT10 | c.2668C>T p.Q890* | Nonsense Mutation (SNP) | VAF 132/648 reads (20%) | catalogued as rs1246893673; called by muse, mutect2, varscan2
- NKX2-5 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 26/462 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.2); catalogued as COSV61299276; called by muse, mutect2
- NOTCH2 | c.6973C>T p.Q2325* | Nonsense Mutation (SNP) | VAF 52/172 reads (30%) | catalogued as CM112324, COSV56682148; called by muse, mutect2, varscan2
- NPR3 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 256/674 reads (38%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV54090080; called by muse, mutect2, varscan2
- NR5A2 | c.1330G>C p.D444H (on ENST00000367362 / NM_205860.3; = p.D398H on NM_003822.5) | Missense Mutation (SNP) | VAF 88/275 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52660360; called by muse, mutect2, varscan2
- OR51M1 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 145/395 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.059); catalogued as rs779170296; called by muse, mutect2, varscan2
- PIKFYVE | c.699G>C p.L233F | Missense Mutation (SNP) | VAF 175/606 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs777357869; called by muse, mutect2, varscan2
- PLEKHA5 | c.910A>T p.I304F | Missense Mutation (SNP) | VAF 109/264 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as rs1565550836; called by muse, mutect2, varscan2
- PRKDC | c.12049G>C p.E4017Q | Missense Mutation (SNP) | VAF 66/161 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); catalogued as rs375321876; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SDR9C7 | c.311C>G p.A104G | Missense Mutation (SNP) | VAF 9/186 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53290814; called by muse, mutect2
- SLC2A1 | c.158G>T p.G53V | Missense Mutation (SNP) | VAF 13/412 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.217); catalogued as rs796053246; ClinVar: uncertain significance; called by muse, mutect2
- SLC38A4 | c.1076G>A p.R359Q | Missense Mutation (SNP) | VAF 159/316 reads (50%) | SIFT tolerated (0.27); PolyPhen probably damaging (1); catalogued as rs1311032019, COSV56969984; called by muse, mutect2, varscan2
- SLC41A3 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 113/422 reads (27%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs1289535326; called by muse, mutect2, varscan2
- SPACA7 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 25/203 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs779002404, COSV52098902; called by muse, mutect2, varscan2
- TGOLN2 | c.287A>G p.N96S | Missense Mutation (SNP) | VAF 420/1262 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.225); catalogued as rs1325016975; called by muse, varscan2
- TRIM67 | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 128/450 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1223330470; called by muse, mutect2, varscan2
- UNC80 | c.8554C>T p.R2852C | Missense Mutation (SNP) | VAF 178/716 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs1369756905, COSV55897971; called by muse, mutect2, varscan2
- ABCA5 | c.4203_4221del p.K1402Tfs*2 | Frame Shift Del (DEL) | VAF 49/164 reads (30%) | called by mutect2, pindel, varscan2
- ACACA | c.1509G>T p.M503I | Missense Mutation (SNP) | VAF 105/398 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ADAM30 | c.2241A>T p.K747N | Missense Mutation (SNP) | VAF 158/605 reads (26%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADM5 | c.208C>G p.R70G | Missense Mutation (SNP) | VAF 189/732 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- ALDH1L1 | c.2654-7C>G | Splice Region (SNP) | VAF 50/502 reads (10%) | called by muse, mutect2
- AMER1 | c.2426_2436del p.F809* | Frame Shift Del (DEL) | VAF 134/660 reads (20%) | called by mutect2, pindel, varscan2
- ANO1 | c.2296_2324del p.K766Gfs*35 | Frame Shift Del (DEL) | VAF 67/477 reads (14%) | called by mutect2, pindel
- APOB | c.9406C>G p.R3136G | Missense Mutation (SNP) | VAF 168/564 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATP4A | c.665G>A p.C222Y | Missense Mutation (SNP) | VAF 252/908 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- BRCA1 | c.752A>T p.K251M | Missense Mutation (SNP) | VAF 47/174 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- C11orf16 | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 181/687 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- C11orf16 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 181/693 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- C16orf89 | c.1170A>C p.R390S | Missense Mutation (SNP) | VAF 116/476 reads (24%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAPN12 | c.804+1G>T p.X268_splice | Splice Site (SNP) | VAF 23/593 reads (4%) | called by muse, mutect2
- CHAMP1 | c.1135T>G p.S379A | Missense Mutation (SNP) | VAF 214/426 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- CHODL | c.677C>A p.P226H | Missense Mutation (SNP) | VAF 87/358 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHRD | c.749G>C p.R250T | Missense Mutation (SNP) | VAF 52/1415 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); called by muse, mutect2
- CKAP5 | c.1447G>C p.D483H | Missense Mutation (SNP) | VAF 132/352 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CNGA3 | c.1505T>A p.V502E | Missense Mutation (SNP) | VAF 474/1565 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CSPP1 | c.1862G>C p.G621A (on ENST00000676605; = p.G580A on NM_024790.6) | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.799); called by muse, mutect2
- CXCR1 | c.157A>T p.S53C | Missense Mutation (SNP) | VAF 38/818 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2
- DNAJC21 | c.1466G>T p.C489F | Missense Mutation (SNP) | VAF 21/283 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.742); called by muse, mutect2
- EPB41L3 | c.2790G>C p.Q930H | Missense Mutation (SNP) | VAF 226/348 reads (65%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ERICH3 | c.2590G>A p.A864T | Missense Mutation (SNP) | VAF 81/261 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- EVPL | c.1244C>G p.P415R | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- FER1L5 | c.6271_*15del | Nonstop Mutation (DEL) | VAF 136/452 reads (30%) | called by mutect2, pindel
- FGF2 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 206/406 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- FOXD4L5 | c.839G>A p.G280E | Missense Mutation (SNP) | VAF 368/2397 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GABRB1 | c.665A>T p.K222M | Missense Mutation (SNP) | VAF 78/239 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- GABRR2 | c.871C>A p.P291T | Missense Mutation (SNP) | VAF 97/207 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GDPD4 | c.284T>G p.L95R | Missense Mutation (SNP) | VAF 97/433 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- GLCE | c.401_421del p.E134_Y140del | In Frame Del (DEL) | VAF 189/628 reads (30%) | called by mutect2, pindel, varscan2
- GRIK3 | c.1633C>T p.R545* | Nonsense Mutation (SNP) | VAF 112/378 reads (30%) | called by muse, mutect2, varscan2
- IGLV3-27 | c.149dup p.Y50* | Nonsense Mutation (INS) | VAF 208/888 reads (23%) | called by mutect2, pindel, varscan2
- IL34 | c.568_584del p.D190Sfs*57 | Frame Shift Del (DEL) | VAF 61/225 reads (27%) | called by mutect2, pindel, varscan2
- JCAD | c.2878G>A p.E960K | Missense Mutation (SNP) | VAF 279/624 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- L3MBTL1 | c.1519C>T p.P507S (on ENST00000418998 / NM_001377303.1; = p.P417S on NM_015478.7) | Missense Mutation (SNP) | VAF 143/440 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MACF1 | c.14930C>A p.S4977Y (on ENST00000372915; = p.S2910Y on NM_012090.5) | Missense Mutation (SNP) | VAF 174/667 reads (26%) | called by muse, mutect2, varscan2
- MAP3K19 | c.1628A>T p.K543M | Missense Mutation (SNP) | VAF 134/405 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MICA | c.541C>A p.H181N | Missense Mutation (SNP) | VAF 149/587 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- MTDH | c.1643C>G p.S548* | Nonsense Mutation (SNP) | VAF 9/266 reads (3%) | called by muse, mutect2
- MTUS1 | c.1430_1445del p.P477Qfs*9 | Frame Shift Del (DEL) | VAF 151/404 reads (37%) | called by mutect2, pindel, varscan2
- MYO7A | c.1489G>C p.D497H | Missense Mutation (SNP) | VAF 191/826 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NLGN1 | c.583A>T p.S195C | Missense Mutation (SNP) | VAF 160/864 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NOD1 | c.1012G>T p.V338F | Missense Mutation (SNP) | VAF 40/950 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.013); called by muse, mutect2
- NONO | c.461A>G p.N154S | Missense Mutation (SNP) | VAF 86/1124 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2
- PARD3 | c.3572A>C p.Q1191P | Missense Mutation (SNP) | VAF 149/323 reads (46%) | SIFT tolerated, low confidence (0.29); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PBXIP1 | c.395C>A p.S132* | Nonsense Mutation (SNP) | VAF 169/473 reads (36%) | called by muse, mutect2, varscan2
- PCDHA13 | c.1069C>G p.L357V | Missense Mutation (SNP) | VAF 148/507 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- PEX1 | c.250C>A p.L84I | Missense Mutation (SNP) | VAF 46/623 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- PI4K2B | c.354A>T p.E118D | Missense Mutation (SNP) | VAF 78/188 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PLXNA2 | c.1590G>T p.W530C | Missense Mutation (SNP) | VAF 163/638 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PPP4C | c.5C>G p.A2G | Missense Mutation (SNP) | VAF 12/394 reads (3%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); called by muse, mutect2
- PRPF8 | c.5988T>G p.N1996K | Missense Mutation (SNP) | VAF 118/843 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- RAB33A | c.403T>A p.C135S | Missense Mutation (SNP) | VAF 235/527 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RAD51B | c.1188G>C p.Q396H | Missense Mutation (SNP) | VAF 61/1020 reads (6%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, mutect2
- RGPD3 | c.3234A>C p.K1078N | Missense Mutation (SNP) | VAF 476/1478 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SBSN | c.571G>T p.G191* | Nonsense Mutation (SNP) | VAF 378/1444 reads (26%) | called by muse, mutect2, varscan2
- SCN2A | c.1310A>G p.E437G | Missense Mutation (SNP) | VAF 111/491 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SHB | c.1293C>A p.S431R | Missense Mutation (SNP) | VAF 159/671 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SHOX2 | c.159C>A p.S53R | Missense Mutation (SNP) | VAF 199/725 reads (27%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- SLC6A19 | c.1474A>T p.I492F | Missense Mutation (SNP) | VAF 684/1513 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- SMIM26 | c.263C>T p.T88I | Missense Mutation (SNP) | VAF 182/680 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SP140 | c.1069T>A p.S357T | Missense Mutation (SNP) | VAF 103/373 reads (28%) | SIFT tolerated (0.73); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- STAC | c.272G>A p.S91N | Missense Mutation (SNP) | VAF 31/909 reads (3%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.469); called by muse, mutect2
- SUPT5H | c.339_341del p.V114del | In Frame Del (DEL) | VAF 38/154 reads (25%) | called by pindel, varscan2
- SYNE2 | c.9887C>G p.P3296R | Missense Mutation (SNP) | VAF 31/487 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.118); called by muse, mutect2
- TAFA4 | c.402_411+4del p.X134_splice | Splice Site (DEL) | VAF 83/215 reads (39%) | called by mutect2, pindel, varscan2
- TCOF1 | c.3820T>G p.S1274A (on ENST00000377797 / NM_001135243.1; = p.S1197A on NM_000356.4) | Missense Mutation (SNP) | VAF 278/889 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- TERF2 | c.1171G>C p.E391Q | Missense Mutation (SNP) | VAF 183/638 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- TFEC | c.238G>C p.A80P | Missense Mutation (SNP) | VAF 44/197 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TNPO3 | c.371G>A p.G124E | Missense Mutation (SNP) | VAF 138/537 reads (26%) | SIFT tolerated (0.95); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- TSHZ1 | c.1841C>T p.S614F (on ENST00000580243 / NM_001308210.2; = p.S569F on NM_005786.6) | Missense Mutation (SNP) | VAF 131/546 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- USP14 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 77/336 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VCPIP1 | c.230A>C p.H77P | Missense Mutation (SNP) | VAF 89/320 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- VNN1 | c.452dup p.C152Vfs*4 | Frame Shift Ins (INS) | VAF 97/260 reads (37%) | called by mutect2, pindel, varscan2
- ZNF213 | c.801C>G p.D267E | Missense Mutation (SNP) | VAF 95/269 reads (35%) | SIFT tolerated (0.91); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF496 | c.532G>T p.G178W | Missense Mutation (SNP) | VAF 53/158 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF514 | c.436A>G p.T146A | Missense Mutation (SNP) | VAF 176/507 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTSL2 | c.1128A>C p.S376= | Silent (SNP) | VAF 212/709 reads (30%) | called by muse, mutect2, varscan2
- FASTKD1 | c.231G>A p.K77= | Silent (SNP) | VAF 70/338 reads (21%) | catalogued as COSV70006980; called by muse, mutect2, varscan2
- GALNT14 | c.411C>T p.R137= | Silent (SNP) | VAF 82/360 reads (23%) | called by muse, mutect2, varscan2
- GLI1 | c.669A>G p.R223= | Silent (SNP) | VAF 173/363 reads (48%) | called by muse, mutect2, varscan2
- GPR149 | c.2001G>T p.G667= | Silent (SNP) | VAF 48/222 reads (22%) | catalogued as COSV101078152, COSV67668118; called by muse, mutect2, varscan2
- HRH2 | c.339C>T p.S113= | Silent (SNP) | VAF 255/1066 reads (24%) | called by muse, mutect2, varscan2
- IGKV2D-24 | c.204T>C p.P68= | Silent (SNP) | VAF 219/743 reads (29%) | catalogued as rs1351973007; called by muse, mutect2, varscan2
- LILRB4 | c.390G>A p.P130= | Silent (SNP) | VAF 185/413 reads (45%) | catalogued as rs372420039; called by muse, mutect2, varscan2
- MB21D2 | c.1212C>A p.R404= | Silent (SNP) | VAF 172/948 reads (18%) | catalogued as COSV101165030; called by muse, mutect2, varscan2
- METTL18 | c.396G>A p.V132= | Silent (SNP) | VAF 109/359 reads (30%) | called by muse, mutect2, varscan2
- MGAT5B | c.1221C>G p.A407= | Silent (SNP) | VAF 110/531 reads (21%) | called by muse, mutect2, varscan2
- MUC22 | c.168T>G p.T56= | Silent (SNP) | VAF 66/429 reads (15%) | called by muse, mutect2, varscan2
- NF1 | c.2838C>T p.D946= | Silent (SNP) | VAF 174/630 reads (28%) | catalogued as rs147188807; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR5M8 | c.759C>A p.T253= | Silent (SNP) | VAF 83/252 reads (33%) | catalogued as rs777315851; called by muse, mutect2, varscan2
- OR6C75 | c.657C>A p.I219= | Silent (SNP) | VAF 204/421 reads (48%) | catalogued as rs375544134; called by muse, mutect2, varscan2
- OR9Q2 | c.222G>A p.S74= | Silent (SNP) | VAF 124/501 reads (25%) | catalogued as rs760143408, COSV61113093; called by muse, mutect2, varscan2
- OXER1 | c.1197G>A p.R399= | Silent (SNP) | VAF 228/713 reads (32%) | catalogued as rs142162926; called by muse, mutect2, varscan2
- PITPNM2 | c.3303G>C p.L1101= | Silent (SNP) | VAF 179/388 reads (46%) | called by muse, mutect2, varscan2
- PRPF6 | c.825G>A p.T275= | Silent (SNP) | VAF 214/682 reads (31%) | catalogued as rs201487454, COSV99411686; called by muse, mutect2, varscan2
- ROR2 | c.2349C>T p.N783= | Silent (SNP) | VAF 141/399 reads (35%) | catalogued as rs761291207, COSV100995391; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCNN1B | c.1902C>T p.D634= | Silent (SNP) | VAF 59/515 reads (11%) | catalogued as rs995687895; called by muse, mutect2, varscan2
- SEPTIN12 | c.912C>T p.N304= | Silent (SNP) | VAF 183/588 reads (31%) | called by muse, mutect2, varscan2
- SHC3 | c.1263A>T p.A421= | Silent (SNP) | VAF 52/184 reads (28%) | called by muse, mutect2, varscan2
- SLC12A1 | c.2925C>T p.I975= | Silent (SNP) | VAF 73/334 reads (22%) | called by muse, mutect2, varscan2
- SVEP1 | c.2637C>T p.Y879= | Silent (SNP) | VAF 75/246 reads (30%) | called by muse, mutect2, varscan2
- TBC1D9B | c.2550C>T p.S850= | Silent (SNP) | VAF 313/647 reads (48%) | called by muse, mutect2, varscan2
- TMEM186 | c.351G>C p.L117= | Silent (SNP) | VAF 176/640 reads (28%) | called by muse, mutect2, varscan2
- TMX2 | c.741T>G p.S247= | Silent (SNP) | VAF 100/385 reads (26%) | called by muse, mutect2, varscan2
- TUBA1A | c.582C>T p.T194= | Silent (SNP) | VAF 14/422 reads (3%) | called by muse, mutect2
- UBXN7 | c.1455A>C p.V485= | Silent (SNP) | VAF 63/556 reads (11%) | called by muse, varscan2
- WNT10B | c.297C>T p.G99= | Silent (SNP) | VAF 132/255 reads (52%) | called by muse, mutect2, varscan2
- ZNF280A | c.558A>T p.G186= | Silent (SNP) | VAF 40/466 reads (9%) | called by muse, mutect2
- ZNF454 | c.39G>A p.S13= | Silent (SNP) | VAF 158/698 reads (23%) | catalogued as rs770644793, COSV100194756; called by muse, mutect2, varscan2
- ZNF680 | c.570A>T p.S190= | Silent (SNP) | VAF 51/179 reads (28%) | called by muse, mutect2, varscan2
- AC017104.4 | chr2:231509270 G>T | 5'Flank (SNP) | VAF 191/620 reads (31%) | called by muse, mutect2, varscan2
- AC024940.1 | n.3772T>A | RNA (SNP) | VAF 133/420 reads (32%) | called by muse, mutect2, varscan2
- C19orf12 | c.194-2375C>T | Intron (SNP) | VAF 54/181 reads (30%) | called by muse, mutect2, varscan2
- CAD | c.-40C>G | 5'UTR (SNP) | VAF 180/626 reads (29%) | called by muse, mutect2, varscan2
- CMC2 | c.154-2206del | Intron (DEL) | VAF 24/96 reads (25%) | called by mutect2, pindel, varscan2
- FMNL1 | c.3211+25C>G | Intron (SNP) | VAF 30/518 reads (6%) | called by muse, mutect2
- FRY | c.8470-1760G>T | Intron (SNP) | VAF 40/110 reads (36%) | called by muse, mutect2, varscan2
- GHRHR | c.974+21G>C | Intron (SNP) | VAF 131/696 reads (19%) | called by muse, mutect2, varscan2
- KRT17P5 | n.1178C>G | RNA (SNP) | VAF 117/632 reads (19%) | called by muse, mutect2, varscan2
- MRNIP | chr5:179860595 A>C | 5'Flank (SNP) | VAF 70/805 reads (9%) | called by muse, mutect2
- PKD1P6 | n.4205G>A | RNA (SNP) | VAF 404/1449 reads (28%) | catalogued as rs764452747; called by muse, mutect2, varscan2
- PLXNC1 | c.3775+118_3775+131del | Intron (DEL) | VAF 43/213 reads (20%) | called by mutect2, pindel, varscan2
- PRPF39 | c.451-325C>G | Intron (SNP) | VAF 47/350 reads (13%) | called by muse, mutect2, varscan2
- SFTPA1 | c.-23-172C>T | Intron (SNP) | VAF 79/190 reads (42%) | called by muse, mutect2, varscan2
- SIGLEC10 | c.706+45G>C | Intron (SNP) | VAF 64/220 reads (29%) | called by muse, mutect2, varscan2
- TULP3 | c.-47C>T | 5'UTR (SNP) | VAF 32/96 reads (33%) | catalogued as rs199562240; called by muse, mutect2, varscan2
- ZNF599 | c.241+1727C>A | Intron (SNP) | VAF 99/339 reads (29%) | called by muse, mutect2, varscan2
- ZSWIM7 | c.-33C>T | 5'UTR (SNP) | VAF 341/713 reads (48%) | catalogued as rs771857833; called by muse, mutect2, varscan2
